Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4343, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4343-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

- 1: SP: Rt. kidney
- 2: SP: Right adrenal
- 3: SP: Paracaval lymph nodes

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE (SEE NOTE), NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 7 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS MILD INTERSTITIAL FIBROSIS AND ARTERIAL SCLEROSIS.

NOTE: THE AREA SHOWING GRADE III NUCLEAR FEATURES IS ONLY FOCAL.

- 2) ADRENAL, RIGHT; ADRENALECTOMY:
- UNREMARKABLE ADRENAL GLAND, NEGATIVE FOR CARCINOMA.
- 3) LYMPH NODES, PARACAVAL; BIOPSY:
- SEVEN BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/7).

1) The specimen is received fresh for frozen section, labeled "Right Kidney". It consists of a kidney with attached perirenal adipose tissue covered by Gerota's fascia. The entire specimen measures 19 x 13 x 6 cm and weighs 850 grams. The attached portion of ureter measures 0.5 cm in length, 0.4 cm in diameter and is grossly unremarkable. The kidney itself measures 12 x 6.5 x 5 cm in greatest dimensions. The entire fascial resection margin is inked black. The specimen is bivalved to reveal a poorly-circumscribed, variegated, soft to firm, tan-white to yellow, focally hemorrhagic, primarily cortical tumor mass in the middle portion of the kidney measuring 7 x 5.5 x 5 cm in greatest dimension. This mass extends beyond the renal capsule into the perirenal adipose tissue, but does not appear to extend through the Gerota's fascia. The mass does not involve the calyces of the renal pelvis. The renal vessels are grossly unremarkable. The remainder of the renal parenchyma is tan-brown and grossly unremarkable. A portion of the tumor is utilized for frozen section diagnosis. A photograph of the specimen is taken. A portion of the tumor is submitted for TPS studies. Representative sections are submitted.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

FSC - frozen section control
UVM - ureteral vascular margins
TK - tumor with adjacent uninvolved kidney
TF - tumor in perirenal fat
TGF - tumor with Gerota's fascia
NK - grossly normal kidney

2) The specimen is received in formalin, labeled "Right Adrenal". It consists of an adrenal with attached adipose tissue, the entire specimen measuring 3.2 x 3.3 x 0.8 cm in greatest dimensions. The adrenal gland itself measures 5.4 x 2.7 x 0.6 cm. Serial sectioning through the specimen reveals areas of hemorrhage in the medulla. No discrete gross lesions are appreciated. Representative sections are submitted.

Summary of Sections:

U - undesignated

Parenchyma a

3) The specimen is received in formalin, labeled "Paracaval Lymph Nodes". It consists of a 4 x 3.6 x 1.4 cm aggregate of adipose tissue fragments. Multiple lymph nodes ranging in size from 0.4 up to 1.4 cm in greatest dimension are identified. The lymph nodes are entirely submitted.

Summary of Sections:

LN - lymph nodes
BLN - bisected lymph nodes

Summary of Sections:

Part 1: SP: Rt. kidney

Block	Sect. Site	PCs
1	FSC	1
2	NK	2
2	TF	2
1	TGF	1
3	TK	3
1	UVM	4

Part 2: SP: Right adrenal

Block	Sect. Site	PCs
2	U	2

Part 3: SP: Paracaval lymph nodes

Block	Sect. Site	PCs
1	BLN	2
2	LN	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. FAVOR CLEAR CELL.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 4be426cd-6ea1-464b-b4cd-5644e3a3bb36 (TCGA-BP-4343.D02DBCD3-9920-421A-99F0-16FE6BA37670.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).